Gene-level copy-number profile of tumor specimen TCGA-60-2698-01A from TCGA case TCGA-60-2698, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.4 years (22,800 days).
Specimen TCGA-60-2698-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.22c5baf3-dd84-458c-a020-ce68f305e6d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2698-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac3457f6-ef50-4266-82eb-ed785337221e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,138; copy number 2: 23,969; copy number 3: 25,089; copy number 4: 5,877; copy number 5: 1,837; copy number 6: 780; copy number 7: 14; copy number 8: 839; copy number 9: 89; copy number 10: 91; copy number 11: 10; copy number 13: 24; copy number 24: 19; copy number 34: 26; copy number 49: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2698-01A-01D-0844-01): tumor purity 0.26, ploidy 5.65, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,115 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:156,037,701–156,539,138, 1 gene, copy number 8 (within-gene range 3–8): KCNAB1.
- chr3:156,143,570–156,540,627, 1 gene, copy number 8 (within-gene range 3–8): AC091607.2.
- chr3:156,441,157–186,110,318, 459 genes, copy number 8–9 (broad region; genes not listed).
- chr6:60,281,444–62,611,327, 14 genes, copy number 7 (within-gene range 3–7): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr7:54,542,325–56,484,386, 67 genes, copy number 9–13 (broad region; genes not listed).
- chr11:68,941,503–71,252,577, 58 genes, copy number 11–49 (within-gene range 5–49): AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:84,720,826–89,808,575, 104 genes, copy number 8 (broad region; genes not listed).
- chr12:19,129,752–19,376,400, 1 gene, copy number 8 (within-gene range 4–8): PLEKHA5.
- chr12:19,303,480–34,249,958, 279 genes, copy number 8 (broad region; genes not listed).
- chr18:316,737–4,459,458, 91 genes, copy number 10 (broad region; genes not listed).
- chr19:28,790,812–30,713,538, 40 genes, copy number 8: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.

Autosomal genes at a single copy (total copy number 1): 1,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
